Somatic mutation profile of tumor specimen TCGA-77-8133-01A (aliquot TCGA-77-8133-01A-12D-2244-08) from TCGA case TCGA-77-8133, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.3 years (27,139 days).
Specimen TCGA-77-8133-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9cbfa47-689e-4335-96c6-d031d0425e43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-8133-10A (Blood Derived Normal), aliquot TCGA-77-8133-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61e0588c-8cc2-4d79-b543-ccce81963bcf

The open-access MAF lists 408 somatic variants for this specimen: 313 protein-altering or splice-affecting, 91 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 265, Silent 91, Nonsense Mutation 21, Frame Shift Del 10, Splice Site 9, Frame Shift Ins 4, RNA 3, Splice Region 2, Nonstop Mutation 1, Intron 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs104894104, CM014526, CX073790, COSV58704067, COSV58704478, COSV58719419; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 20/60 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2M | c.2558G>T p.R853L | Missense Mutation (SNP) | VAF 66/339 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100588501; called by muse, mutect2, varscan2
- ADCY7 | c.2969T>C p.V990A | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99575738; called by muse, mutect2, varscan2
- ADRA1A | c.132C>A p.N44K | Missense Mutation (SNP) | VAF 69/444 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99370056; called by muse, mutect2, varscan2
- AJAP1 | c.822G>C p.E274D | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as COSV100981517; called by muse, mutect2, varscan2
- AMPH | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100341144; called by muse, mutect2, varscan2
- APBB1IP | c.702T>G p.F234L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); catalogued as COSV100770880; called by muse, mutect2, varscan2
- ARHGAP31 | c.1277G>T p.R426L | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV51790326, COSV99956677; called by muse, mutect2, varscan2
- ARHGAP31 | c.3408G>T p.E1136D | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99956680; called by muse, mutect2
- ARMC10 | c.879A>G p.I293M | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.544); catalogued as COSV100085656; called by muse, mutect2
- ASCC2 | c.1378G>T p.G460C | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.401); catalogued as COSV100316072; called by muse, mutect2, varscan2
- ATP10A | c.1976G>T p.G659V | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV100790965; called by muse, mutect2, varscan2
- ATP13A2 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100453968; called by muse, mutect2, varscan2
- ATP2A2 | c.2236G>T p.V746F | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100428441; called by muse, mutect2, varscan2
- ATP7B | c.4387C>A p.Q1463K | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV99666127; called by muse, mutect2
- AXIN2 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV100196030; called by muse, mutect2, varscan2
- BAZ1B | c.4324A>G p.K1442E | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV100289622; called by muse, mutect2, varscan2
- BFSP2 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.824); catalogued as COSV100183581; called by muse, mutect2, varscan2
- BMP7 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 8/189 reads (4%) | catalogued as COSV101215590; called by muse, mutect2
- BRWD3 | c.4013A>G p.Q1338R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.084); catalogued as rs1041016053, COSV100955725; called by muse, mutect2, varscan2
- BTAF1 | c.2812A>G p.T938A | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99794998; called by muse, mutect2, varscan2
- BTN2A2 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); catalogued as COSV100760253; called by muse, mutect2, varscan2
- C12orf50 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.124); catalogued as COSV100072028; called by muse, mutect2, varscan2
- C14orf93 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 24/137 reads (18%) | catalogued as rs766879288, COSV100136627; called by muse, mutect2, varscan2
- C1QTNF2 | c.395C>A p.T132K (on ENST00000393975; = p.T87K on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0.3); catalogued as COSV101220831; called by muse, mutect2, varscan2
- CACNA1H | c.1102T>A p.W368R | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100671062; called by muse, mutect2, varscan2
- CACNA1I | c.2249G>A p.R750H | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100359414; called by muse, mutect2, varscan2
- CACUL1 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV100432434; called by muse, mutect2, varscan2
- CCDC172 | c.440T>A p.L147* | Nonsense Mutation (SNP) | VAF 23/49 reads (47%) | catalogued as COSV100319667; called by muse, mutect2, varscan2
- CCDC85A | c.845A>C p.H282P | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); catalogued as COSV101339399; called by muse, mutect2, varscan2
- CCER1 | c.600C>A p.D200E | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100726949; called by muse, mutect2
- CCNF | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as rs201290179; called by muse, mutect2, varscan2
- CDHR2 | c.1691G>A p.G564E | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as rs1429522139, COSV99991138; called by muse, mutect2, varscan2
- CEACAM18 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs759033064, COSV67284558; called by muse, varscan2
- CFAP46 | c.5612C>T p.A1871V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); catalogued as rs1342022589, COSV54155514; called by muse, mutect2, varscan2
- CFAP61 | c.1912A>T p.K638* | Nonsense Mutation (SNP) | VAF 69/192 reads (36%) | catalogued as COSV99843601; called by muse, mutect2, varscan2
- CFHR2 | c.614-1G>T p.X205_splice | Splice Site (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100804261; called by muse, mutect2
- CHPF | c.1480G>T p.V494L | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV60534058, COSV99704726; called by muse, mutect2
- CNTNAP2 | c.1279A>T p.T427S | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100663502; called by muse, mutect2, varscan2
- CNTNAP5 | c.3351C>A p.D1117E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101442929, COSV101443132; called by muse, mutect2, varscan2
- COL12A1 | c.2000A>G p.K667R | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.063); catalogued as rs1282131807, COSV100485514; called by muse, mutect2, varscan2
- COL19A1 | c.2713G>C p.G905R | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757772326, COSV100505412; called by muse, mutect2, varscan2
- COL28A1 | c.1894C>T p.P632S | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.066); catalogued as COSV101258352; called by muse, mutect2, varscan2
- COL4A2 | c.205del p.Q69Rfs*30 | Frame Shift Del (DEL) | VAF 15/99 reads (15%) | catalogued as COSV100847248, COSV64629932; called by mutect2, pindel, varscan2
- COL6A6 | c.3115A>G p.I1039V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as COSV100649929; called by muse, mutect2
- COX15 | c.595T>A p.W199R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99186809; called by muse, mutect2, varscan2
- CPQ | c.1054-2A>T p.X352_splice | Splice Site (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99610832; called by muse, mutect2, varscan2
- CPS1 | c.4483A>T p.S1495C | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.161); catalogued as COSV99242348; called by muse, mutect2, varscan2
- CPXCR1 | c.880C>A p.H294N | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99342027; called by muse, mutect2, varscan2
- CRISP1 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.138); catalogued as COSV100236661, COSV59993214; called by muse, mutect2, varscan2
- CRYBG2 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1257362110; called by muse, mutect2
- CSMD1 | c.7243A>C p.T2415P (on ENST00000520002; = p.T2414P on NM_033225.6) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV100144722; called by muse, mutect2, varscan2
- CSMD1 | c.2944C>A p.H982N (on ENST00000520002; = p.H981N on NM_033225.6) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV100144725; called by muse, mutect2
- CSMD3 | c.7028C>A p.P2343Q (on ENST00000297405 / NM_001363185.1; = p.P2239Q on NM_052900.3) | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52280029; called by muse, mutect2, varscan2
- CTNND2 | c.1561C>G p.P521A | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV100472828; called by muse, mutect2, varscan2
- CYP2B6 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.419); catalogued as rs200458614, COSV57845135, COSV57845291; called by muse, mutect2, varscan2
- CYP4F8 | c.226G>T p.V76F | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV100358032, COSV57853166; called by muse, mutect2, varscan2
- DAB1 | c.1292G>T p.R431M (on ENST00000371231; = p.R398M on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.862); catalogued as rs146726559; called by muse, mutect2, varscan2
- DCC | c.1069A>T p.K357* | Nonsense Mutation (SNP) | VAF 78/232 reads (34%) | catalogued as COSV100498555; called by muse, mutect2, varscan2
- DCDC2 | c.818C>A p.P273H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.921); catalogued as COSV101015950; called by muse, mutect2, varscan2
- DDX20 | c.2134C>G p.Q712E | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100861996; called by muse, mutect2, varscan2
- DDX49 | c.790C>G p.L264V | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV99447251; called by muse, mutect2, varscan2
- DENND4A | c.413A>T p.Q138L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101475272; called by muse, mutect2
- DGKI | c.2651G>T p.W884L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99932771; called by muse, mutect2
- DGKI | c.2649G>T p.W883C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV99932774; called by muse, mutect2
- DHTKD1 | c.661A>T p.M221L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV99536110; called by muse, mutect2
- DIO3 | c.698A>T p.Q233L | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.188); catalogued as COSV100832056; called by muse, mutect2, varscan2
- DLC1 | c.455C>A p.P152H | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV99361560; called by muse, mutect2, varscan2
- DMXL1 | c.605G>A p.W202* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as COSV100223426, COSV100224010; called by muse, mutect2, varscan2
- DMXL2 | c.5765A>G p.D1922G | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs368702687; called by muse, mutect2, varscan2
- DNAH1 | c.10914C>A p.N3638K | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.312); catalogued as COSV101324908; called by muse, mutect2
- DNAH5 | c.10970A>T p.D3657V | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99445896; called by muse, mutect2, varscan2
- DNAH5 | c.4342G>T p.E1448* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99445899; called by mutect2, varscan2
- DSP | c.5887A>T p.T1963S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV101131192; called by muse, mutect2, varscan2
- DTD1 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.121); catalogued as rs769322465, COSV101079711; called by muse, mutect2, varscan2
- EPHA5 | c.3054G>T p.K1018N | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99896810; called by muse, mutect2, varscan2
- EPS8 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as COSV99842731; called by muse, mutect2, varscan2
- ETNPPL | c.679G>T p.G227C | Missense Mutation (SNP) | VAF 68/248 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV99625026; called by muse, varscan2
- EVX2 | c.51C>G p.H17Q | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.806); catalogued as COSV100420567; called by muse, mutect2, varscan2
- FAM136A | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.119); catalogued as COSV99231894; called by muse, mutect2, varscan2
- FAM149A | c.2258A>G p.Y753C (on ENST00000356371 / NM_001367768.2; = p.Y462C on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as rs1390118401, COSV99906374; called by muse, mutect2
- FAM221A | c.649G>T p.V217F | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as rs1562528738, COSV100794294; called by muse, mutect2, varscan2
- FAM227B | c.7G>T p.G3C | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV100174564; called by muse, mutect2, varscan2
- FAM47A | c.1367C>A p.T456N | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.45); catalogued as COSV100649761, COSV60498176; called by muse, mutect2, varscan2
- FAM83B | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as COSV100174120; called by muse, mutect2, varscan2
- FANCI | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV100167564; called by muse, mutect2, varscan2
- FCGBP | c.10153G>T p.G3385W | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761180972; called by muse, mutect2, varscan2
- FCGR3B | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs532028851, COSV99670410; called by muse, mutect2, varscan2
- FGD3 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs749584174, COSV61599267; called by muse, mutect2, varscan2
- FLG | c.1788C>A p.D596E | Missense Mutation (SNP) | VAF 50/368 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.627); catalogued as COSV100910745; called by muse, mutect2, varscan2
- FN1 | c.6228C>A p.Y2076* | Nonsense Mutation (SNP) | VAF 14/87 reads (16%) | catalogued as COSV100116363; called by muse, mutect2, varscan2
- FNBP4 | c.2556G>T p.Q852H | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV99771478; called by muse, mutect2, varscan2
- FOXG1 | c.1114A>T p.I372F | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); catalogued as COSV100486585; called by muse, mutect2, varscan2
- FPR1 | c.449G>C p.W150S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100493949, COSV100494059; called by muse, mutect2
- FRMD1 | c.159C>A p.H53Q | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.306); catalogued as COSV99349540; called by muse, mutect2, varscan2
- FUT8 | c.512G>T p.S171I (on ENST00000360689 / NM_001371534.1; = p.S8I on NM_004480.4) | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.319); catalogued as COSV100651138; called by muse, mutect2, varscan2
- GABRB3 | c.1330G>T p.D444Y | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100158514, COSV54670778; called by muse, mutect2, varscan2
- GABRR3 | c.94C>G p.Q32E | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs916694125, COSV101512265; called by muse, mutect2, varscan2
- GBF1 | c.4282A>T p.N1428Y (on ENST00000369983 / NM_001377137.1; = p.N1427Y on NM_004193.3) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100890348; called by muse, mutect2, varscan2
- GBX1 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV99880766; called by muse, mutect2, varscan2
- GCC2 | c.3102T>G p.D1034E | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV100565289; called by muse, mutect2, varscan2
- GGTLC1 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as COSV99600455; called by muse, mutect2, varscan2
- GPR15 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377521784; called by muse, mutect2, varscan2
- GRIK2 | c.41G>T p.R14M | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV100023821; called by muse, mutect2, varscan2
- GRIK3 | c.639C>A p.D213E | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV100901473; called by muse, mutect2, varscan2
- GRIN1 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.233); catalogued as COSV100159898; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2381A>G p.N794S (on ENST00000265755 / NM_016328.3; = p.N779S on NM_005685.4) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs1452943191, COSV99734175; called by muse, mutect2, varscan2
- HAS1 | c.857G>A p.W286* | Nonsense Mutation (SNP) | VAF 23/137 reads (17%) | catalogued as COSV99708244; called by muse, mutect2, varscan2
- HAS1 | c.701A>G p.Q234R | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV99708245; called by muse, mutect2, varscan2
- HIVEP2 | c.2089C>T p.R697C | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764717749, COSV50131336; called by muse, mutect2, varscan2
- ICA1L | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV100841674; called by muse, mutect2, varscan2
- IGSF8 | c.193T>A p.F65I | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100081546; called by muse, mutect2, varscan2
- IRS2 | c.1847G>T p.C616F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV101018861; called by muse, varscan2
- ITGBL1 | c.1379G>A p.G460D | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101095124; called by muse, mutect2, varscan2
- ITIH3 | c.658A>T p.K220* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV101406904, COSV69647804; called by muse, mutect2
- ITPR3 | c.2519A>G p.Y840C | Missense Mutation (SNP) | VAF 78/205 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100967001; called by muse, mutect2, varscan2
- JCHAIN | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99636309; called by muse, mutect2, varscan2
- KALRN | c.1924A>G p.M642V | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV99562502; called by muse, mutect2
- KATNIP | c.1693G>T p.D565Y | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99850087; called by muse, mutect2, varscan2
- KCND2 | c.88C>A p.P30T | Missense Mutation (SNP) | VAF 58/219 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100474030, COSV58578960; called by muse, mutect2, varscan2
- KCNH1 | c.349C>G p.R117G | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55073425, COSV55081384; called by muse, mutect2, varscan2
- KCNH8 | c.2479C>G p.Q827E | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as COSV100108789; called by muse, mutect2, varscan2
- KCNJ16 | c.440T>G p.V147G | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs779295747, COSV99388022; called by muse, mutect2, varscan2
- KCNJ4 | c.1055A>T p.E352V | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100341040; called by muse, mutect2, varscan2
- KCNN2 | c.1685C>G p.S562C (on ENST00000264773; = p.S774C on NM_021614.4) | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.707); catalogued as COSV53291669, COSV99298919; called by muse, mutect2, varscan2
- KIAA0319 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as COSV100985267; called by muse, mutect2, varscan2
- KIF5A | c.33G>T p.K11N | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV99672537; called by muse, mutect2, varscan2
- KLHL11 | c.1817A>G p.Y606C | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1555622227, COSV100044215; called by muse, mutect2, varscan2
- L1CAM | c.1573C>A p.R525S | Missense Mutation (SNP) | VAF 75/134 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as COSV100648815; called by muse, mutect2, varscan2
- LCP1 | c.1203G>C p.R401S | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99063736; called by muse, mutect2, varscan2
- LEPR | c.2144T>C p.L715P | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100756358; called by muse, mutect2, varscan2
- LIN28A | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV54263179; called by muse, mutect2, varscan2
- LIPK | c.157A>G p.T53A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101344954; called by mutect2, varscan2
- LRFN5 | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747377549, COSV53262238, COSV99982757; called by muse, varscan2
- LRIT1 | c.1105G>T p.G369W | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as COSV100928019; called by muse, varscan2
- LRP1B | c.10861G>T p.D3621Y | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV101253619, COSV101258167, COSV67275672; called by muse, mutect2, varscan2
- LRP6 | c.3922A>C p.N1308H | Missense Mutation (SNP) | VAF 94/222 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99742600; called by muse, mutect2, varscan2
- LRRC36 | c.198+2T>C p.X66_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100325830; called by muse, mutect2
- LRRTM4 | c.392C>A p.P131Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.848); catalogued as COSV101297433; called by muse, mutect2, varscan2
- MAD1L1 | c.2053A>T p.T685S | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as COSV99765343; called by muse, mutect2, varscan2
- MBD3 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99336862; called by muse, mutect2, varscan2
- MDGA2 | c.1131C>A p.Y377* (on ENST00000399232 / NM_001113498.2; = p.Y79* on NM_182830.4) | Nonsense Mutation (SNP) | VAF 21/160 reads (13%) | catalogued as COSV100636496; called by muse, mutect2, varscan2
- MED23 | c.2742G>T p.Q914H | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100644803; called by muse, mutect2, varscan2
- METTL4 | c.1347G>T p.W449C | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100170491; called by muse, mutect2, varscan2
- MLF2 | c.337A>G p.T113A | Missense Mutation (SNP) | VAF 91/385 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV99180060; called by muse, mutect2, varscan2
- MNDA | c.216G>T p.M72I | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100933256, COSV63741864; called by muse, mutect2
- MPDZ | c.1246G>T p.V416F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753084316, COSV100061128; called by muse, mutect2, varscan2
- MSL3 | c.1523G>A p.C508Y (on ENST00000312196 / NM_078629.4; = p.C342Y on NM_006800.4) | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100384598; called by muse, mutect2, varscan2
- MTRR | c.314_315insAG p.N105Kfs*34 (on ENST00000264668; = p.N78Kfs*34 on NM_002454.3 and 4 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 46/175 reads (26%) | catalogued as COSV99241368; called by mutect2, pindel, varscan2
- MTUS2 | c.4106G>A p.R1369K (on ENST00000612955 / NM_001366650.1; = p.R348K on NM_015233.6) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101070783, COSV66419956; called by muse, mutect2, varscan2
- MYH13 | c.5717A>C p.E1906A | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52830309; called by muse, mutect2, varscan2
- MYO1F | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.928); catalogued as COSV57801311; called by muse, mutect2, varscan2
- MYT1L | c.1666C>A p.R556S | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.528); catalogued as COSV101219200, COSV67733063; called by muse, mutect2, varscan2
- NBAS | c.2891G>T p.G964V | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.402); catalogued as COSV99867723; called by muse, mutect2, varscan2
- NCOA7 | c.298A>T p.K100* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as COSV99996597; called by muse, mutect2, varscan2
- NCOR2 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100656967; called by muse, mutect2, varscan2
- NDST4 | c.1280A>C p.Y427S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99995690; called by muse, mutect2, varscan2
- NECAB2 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.086); catalogued as rs1374722120, COSV100533855; called by muse, mutect2
- NETO2 | c.166C>A p.H56N | Missense Mutation (SNP) | VAF 71/225 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.121); catalogued as COSV100292364; called by muse, mutect2, varscan2
- NEU4 | c.859G>T p.A287S (on ENST00000391969 / NM_001167602.3; = p.A299S on NM_080741.4) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.074); catalogued as COSV100371842; called by muse, mutect2
- NIP7 | c.92C>G p.P31R | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as rs145587963, COSV99650644; called by muse, mutect2, varscan2
- NLRC3 | c.1394C>A p.A465E | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.174); catalogued as rs1452666120, COSV100072499; called by muse, mutect2
- NLRP3 | c.11C>A p.T4N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV100275406; called by muse, mutect2, varscan2
- NOS1 | c.1597G>T p.G533C | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100500142; called by muse, mutect2, varscan2
- NOX4 | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 39/104 reads (38%) | catalogued as COSV99629825; called by muse, varscan2
- NPAP1 | c.2489C>A p.P830H | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV61509481, COSV61511172; called by muse, mutect2, varscan2
- NPAP1 | c.2791C>T p.P931S | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.246); catalogued as COSV61504711; called by muse, mutect2, varscan2
- NR2C1 | c.561A>T p.R187S | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100280278; called by muse, mutect2, varscan2
- NUDT7 | c.194G>T p.R65I | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99215949; called by muse, mutect2, varscan2
- NUMA1 | c.2060C>T p.A687V | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1367256092, COSV100705858; called by muse, mutect2, varscan2
- NXPE4 | c.378C>A p.H126Q | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.87); catalogued as COSV100970320; called by muse, mutect2, varscan2
- OLFM3 | c.1347A>T p.R449S (on ENST00000338858 / NM_001288821.1; = p.R429S on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV100128978; called by muse, mutect2, varscan2
- OLFM3 | c.101C>A p.T34N | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs766665047, COSV100128981; called by muse, mutect2, varscan2
- OR10G3 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 82/269 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs768812890, COSV100336068; called by muse, mutect2, varscan2
- OR10K2 | c.415G>T p.G139W | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV100149400; called by muse, mutect2, varscan2
- OR1I1 | c.90G>A p.M30I | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99264746; called by muse, mutect2, varscan2
- OR1J4 | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.424); catalogued as COSV100534254; called by muse, mutect2
- OR1J4 | c.544G>T p.V182F | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.167); catalogued as COSV100534256; called by muse, mutect2
- OR2M4 | c.317C>A p.S106Y | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100141017; called by muse, mutect2, varscan2
- OR2M5 | c.10del p.E4Rfs*127 | Frame Shift Del (DEL) | VAF 30/300 reads (10%) | catalogued as COSV100822843; called by mutect2, pindel, varscan2
- OR4D2 | c.385C>G p.P129A | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101613843; called by muse, mutect2, varscan2
- OR4P4 | c.768C>A p.Y256* | Nonsense Mutation (SNP) | VAF 42/119 reads (35%) | catalogued as COSV100111593; called by muse, mutect2, varscan2
- OR51A2 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV100985014; called by muse, mutect2
- OR52E2 | c.204G>T p.L68F | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58613126; called by muse, mutect2
- OR56A4 | c.452C>A p.A151D | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.559); catalogued as COSV100417479; called by muse, mutect2
- OR5AR1 | c.329C>A p.A110D | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV100265587; called by muse, mutect2, varscan2
- OR5P2 | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV100271223; called by muse, mutect2, varscan2
- OR6B1 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 36/163 reads (22%) | catalogued as COSV101281635; called by muse, mutect2, varscan2
- OR6B1 | c.858C>A p.F286L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV101281636; called by muse, mutect2, varscan2
- OR6C4 | c.530G>A p.C177Y | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101263129; called by muse, mutect2, varscan2
- OR6F1 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100129005; called by muse, mutect2, varscan2
- OR7G2 | c.161C>A p.S54Y | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV100560344; called by muse, mutect2, varscan2
- P2RY6 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 91/186 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs372909665; called by muse, mutect2, varscan2
- PAPPA2 | c.319G>T p.V107F | Missense Mutation (SNP) | VAF 33/278 reads (12%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV62785323; called by muse, mutect2, varscan2
- PCDH10 | c.2215C>A p.R739S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV52099108, COSV99993103; called by muse, mutect2, varscan2
- PCDHA3 | c.743A>G p.K248R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.098); catalogued as COSV100973637; called by muse, mutect2, varscan2
- PCDHA8 | c.1214A>G p.Y405C | Missense Mutation (SNP) | VAF 156/278 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100970503; called by muse, mutect2, varscan2
- PCDHGA12 | c.1111G>T p.V371L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.232); catalogued as COSV99338480; called by muse, mutect2, varscan2
- PGS1 | c.869A>T p.H290L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99428066; called by muse, mutect2
- PIWIL1 | c.716T>C p.I239T | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs745440612, COSV99806081; called by muse, mutect2, varscan2
- PIWIL2 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100769253; called by muse, mutect2, varscan2
- PKHD1 | c.6622G>T p.V2208F | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs768242264, COSV100581544; called by muse, mutect2, varscan2
- PLEKHA7 | c.2007+2T>G p.X669_splice | Splice Site (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100850120; called by muse, mutect2, varscan2
- POU3F2 | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100098998; called by muse, mutect2, varscan2
- PPP3R2 | c.446C>A p.S149Y | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1269621315, COSV100701387; called by muse, mutect2, varscan2
- PRC1 | c.817A>C p.K273Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.217); catalogued as COSV100727052; called by muse, mutect2, varscan2
- PREX2 | c.3140T>C p.I1047T | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99905474, COSV99906672; called by muse, mutect2, varscan2
- PRKACG | c.1005G>T p.E335D | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV55240820; called by muse, mutect2, varscan2
- PRR27 | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1157930868, COSV100748760; called by muse, mutect2, varscan2
- PSKH2 | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99405017; called by muse, mutect2, varscan2
- PTCH2 | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV100941949; called by muse, mutect2, varscan2
- PTPRC | c.3796G>A p.G1266S | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.018); catalogued as COSV100722185; called by muse, mutect2, varscan2
- QTRT2 | c.667C>A p.Q223K | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV99846822; called by muse, mutect2, varscan2
- RADIL | c.1259G>T p.R420M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101271286, COSV99070731; called by muse, mutect2, varscan2
- RELN | c.5423T>A p.F1808Y | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100632702; called by muse, mutect2, varscan2
- RET | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as rs1313331250, CM1110094, COSV60685932; called by muse, mutect2, varscan2
- RFX5 | c.1196G>T p.G399V | Missense Mutation (SNP) | VAF 136/313 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.998); catalogued as COSV51840472; called by muse, mutect2, varscan2
- RGS7 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100465200; called by muse, mutect2, varscan2
- ROBO3 | c.1531G>T p.V511L | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101184945; called by muse, mutect2, varscan2
- RP1L1 | c.6195G>C p.Q2065H | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); catalogued as COSV101223001; called by muse, mutect2, varscan2
- RPS6KA3 | c.1669A>G p.I557V | Missense Mutation (SNP) | VAF 69/112 reads (62%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV101084180; called by muse, mutect2, varscan2
- RTL9 | c.2238G>T p.M746I | Missense Mutation (SNP) | VAF 49/78 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV101511641, COSV71825623; called by muse, mutect2, varscan2
- RYR3 | c.1622A>G p.N541S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.047); catalogued as rs1394811291, COSV101212102, COSV101213425; called by muse, mutect2, varscan2
- SASH1 | c.2966C>T p.A989V | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.195); catalogued as COSV100820958; called by muse, mutect2, varscan2
- SCN1A | c.1144G>T p.D382Y | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM113289, COSV100319538, COSV100319545; called by muse, mutect2, varscan2
- SCN2A | c.5438T>C p.I1813T | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99330378; called by muse, mutect2, varscan2
- SEC61A1 | c.1380C>G p.I460M | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV99684726; called by muse, mutect2, varscan2
- SEL1L2 | c.1987A>G p.I663V | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99532709; called by muse, mutect2, varscan2
- SELL | c.468C>A p.N156K (on ENST00000650983; = p.N143K on NM_000655.5) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99357396, COSV99357923; called by muse, mutect2, varscan2
- SEMA3D | c.1144C>A p.R382S | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs767895363, COSV99406034, COSV99407536; called by muse, mutect2, varscan2
- SEMA6D | c.285A>G p.K95= | Splice Region (SNP) | VAF 5/28 reads (18%) | catalogued as COSV60374869; called by muse, mutect2, varscan2
- SLC15A4 | c.1413A>T p.A471= | Splice Region (SNP) | VAF 14/60 reads (23%) | catalogued as COSV99903440; called by muse, mutect2, varscan2
- SLC16A12 | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100370034; called by muse, mutect2, varscan2
- SLC16A14 | c.963C>A p.F321L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.015); catalogued as COSV99725267; called by muse, mutect2
- SLC2A14 | c.1514T>C p.M505T | Missense Mutation (SNP) | VAF 122/677 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100533604; called by muse, mutect2
- SLC2A2 | c.736C>G p.L246V | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100049134, COSV58586598; called by muse, mutect2, varscan2
- SLC31A1 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as rs758747312, COSV100951911, COSV100951921; called by muse, mutect2, varscan2
- SLC6A15 | c.11A>T p.N4I | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as COSV99880286; called by muse, mutect2, varscan2
- SLC8A3 | c.1980G>T p.L660F (on ENST00000381269 / NM_183002.3; = p.L658F on NM_033262.4) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs750545103, COSV99385343; called by muse, mutect2, varscan2
- SLC9A4 | c.1793C>A p.S598Y | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV99762765; called by muse, mutect2, varscan2
- SLCO2A1 | c.1591A>G p.I531V | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV100188708; called by muse, mutect2, varscan2
- SLCO2B1 | c.294C>A p.N98K | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99214346; called by muse, mutect2, varscan2
- SORBS1 | c.2783G>T p.R928L (on ENST00000361941 / NM_001034954.2; = p.R578L on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV99527543; called by muse, mutect2, varscan2
- SORCS1 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99543961; called by muse, mutect2, varscan2
- SORL1 | c.4369G>T p.A1457S | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0.069); catalogued as COSV99493064; called by muse, mutect2, varscan2
- SP1 | c.1436C>A p.A479D (on ENST00000327443 / NM_138473.3; = p.A472D on NM_003109.1) | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100540446; called by muse, mutect2, varscan2
- SP7 | c.328C>A p.L110I | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.218); catalogued as COSV100381941, COSV58191950; called by muse, mutect2
- SPG11 | c.3277G>T p.G1093W | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99968151; called by muse, mutect2, varscan2
- ST18 | c.55+1G>T p.X19_splice | Splice Site (SNP) | VAF 16/87 reads (18%) | catalogued as COSV99388541; called by muse, mutect2, varscan2
- STARD3NL | c.487C>G p.L163V | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.679); catalogued as COSV50519857, COSV99151565; called by muse, mutect2, varscan2
- STOML3 | c.234G>T p.L78F | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101105180, COSV65510104; called by muse, mutect2, varscan2
- SYNE1 | c.5491G>T p.G1831C (on ENST00000367255 / NM_182961.4; = p.G1838C on NM_033071.3) | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs184779168, COSV99555541; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAS2R1 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101225709; called by muse, mutect2, varscan2
- TAS2R5 | c.797C>G p.S266C | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99924764; called by muse, mutect2, varscan2
- TCTN1 | c.1354C>T p.Q452* (on ENST00000551590 / NM_001173975.3; = p.Q438* on NM_024549.6) | Nonsense Mutation (SNP) | VAF 40/110 reads (36%) | catalogued as COSV99657085; called by muse, mutect2, varscan2
- TGM6 | c.1865T>C p.V622A | Missense Mutation (SNP) | VAF 85/218 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV99171694; called by muse, mutect2, varscan2
- THBS3 | c.1419C>A p.D473E | Missense Mutation (SNP) | VAF 64/407 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.034); catalogued as rs773242038, COSV100857501; called by muse, mutect2, varscan2
- THSD7B | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1230279281, COSV55742071; called by muse, mutect2, varscan2
- TIMP2 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.16); catalogued as COSV99430203; called by muse, mutect2, varscan2
- TLN1 | c.5081C>T p.S1694F | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV59211714; called by muse, mutect2, varscan2
- TM9SF3 | c.387G>T p.W129C | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100951817; called by muse, mutect2, varscan2
- TMCO6 | c.881G>T p.G294V | Missense Mutation (SNP) | VAF 87/192 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.155); catalogued as COSV99347014; called by muse, mutect2, varscan2
- TMEM71 | c.458G>T p.R153M (on ENST00000523829 / NM_001382398.1; = p.R134M on NM_144649.3) | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.114); catalogued as COSV100785551, COSV63459967; called by muse, mutect2, varscan2
- TNXB | c.8447G>T p.G2816V (on ENST00000647633; = p.G2569V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.802); catalogued as COSV100925972; called by muse, mutect2, varscan2
- TOP2A | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 17/49 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.692); catalogued as COSV101396082; called by muse, mutect2, varscan2
- TOR1AIP2 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 37/84 reads (44%) | catalogued as rs747346773, COSV62625758; called by muse, mutect2, varscan2
- TPH2 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 70/296 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV100421949; called by muse, mutect2, varscan2
- TRAPPC10 | c.2966A>T p.Q989L | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV99378260; called by muse, mutect2, varscan2
- TRPA1 | c.2884G>T p.G962C | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100083389; called by muse, mutect2, varscan2
- TRPS1 | c.275G>T p.S92I (on ENST00000220888 / NM_001330599.2; = p.S105I on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs1471963361, COSV55244577, COSV99628884; called by muse, mutect2, varscan2
- TTN | c.86455G>A p.E28819K (on ENST00000591111; = p.E21395K on NM_003319.4) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | PolyPhen probably damaging (0.994); catalogued as rs908278682, COSV100598036; called by muse, mutect2, varscan2
- TTN | c.24673C>A p.Q8225K (on ENST00000591111; = p.Q7298K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | PolyPhen benign (0); catalogued as COSV100598041; called by muse, mutect2, varscan2
- TTN | c.16709A>G p.K5570R (on ENST00000591111; = p.K4643R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/180 reads (18%) | PolyPhen possibly damaging (0.814); catalogued as rs527439656, COSV59965919, COSV60408871; called by muse, mutect2, varscan2
- TUBB4B | c.401A>T p.Q134L | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100457722; called by muse, mutect2
- URI1 | c.518-2A>G p.X173_splice | Splice Site (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100368871; called by mutect2, varscan2
- USP13 | c.1948+1G>T p.X650_splice | Splice Site (SNP) | VAF 89/264 reads (34%) | catalogued as COSV55870780; called by muse, mutect2, varscan2
- VIT | c.1279A>G p.I427V (on ENST00000389975 / NM_001177969.1; = p.I442V on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV101007199; called by muse, mutect2, varscan2
- VPS28 | c.476A>T p.E159V | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV99465450; called by muse, mutect2, varscan2
- VWA3B | c.518A>T p.H173L | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.022); catalogued as COSV101345956; called by muse, mutect2, varscan2
- WDR17 | c.2617C>G p.Q873E | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV54572735, COSV99706973; called by muse, mutect2, varscan2
- ZBED9 | c.1454C>A p.S485Y | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV101509139; called by muse, mutect2, varscan2
- ZBP1 | c.1265G>C p.G422A | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.088); catalogued as COSV100473111, COSV100474009; called by muse, mutect2, varscan2
- ZFHX4 | c.4934C>A p.P1645H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV99257778; called by muse, mutect2, varscan2
- ZIC2 | c.1360T>A p.S454T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV100891763; called by muse, mutect2, varscan2
- ZNF100 | c.797G>A p.C266Y | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as COSV99973791; called by muse, mutect2, varscan2
- ZNF155 | c.1420C>T p.H474Y | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54206333, COSV54207766; called by muse, mutect2, varscan2
- ZNF282 | c.857A>T p.Q286L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100021452; called by muse, varscan2
- ZNF304 | c.1075G>T p.G359* | Nonsense Mutation (SNP) | VAF 3/39 reads (8%) | catalogued as COSV99988437; called by muse, mutect2
- ZNF407 | c.2551A>T p.T851S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as rs1392112690, COSV99995030; called by muse, mutect2, varscan2
- ZNF778 | c.1025G>T p.C342F | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100124311; called by muse, mutect2, varscan2
- ZNF804A | c.1465C>A p.Q489K | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV100166689, COSV100167753; called by muse, mutect2
- ZPLD1 | c.988C>T p.Q330* (on ENST00000466937 / NM_001329788.1; = p.Q346* on NM_175056.2) | Nonsense Mutation (SNP) | VAF 17/86 reads (20%) | catalogued as rs777012894, COSV100082969; called by muse, mutect2, varscan2
- ZXDA | c.2356G>T p.E786* | Nonsense Mutation (SNP) | VAF 4/55 reads (7%) | catalogued as COSV100699339; called by muse, mutect2
- ACTL6B | c.760-21_760-1del p.X254_splice | Splice Site (DEL) | VAF 29/107 reads (27%) | called by mutect2, pindel
- ANGPTL8 | c.1_2del p.M1? | Frame Shift Del (DEL) | VAF 23/82 reads (28%) | called by mutect2, pindel, varscan2
- ATG2A | c.1781_1785dup p.E596Tfs*28 | Frame Shift Ins (INS) | VAF 9/41 reads (22%) | called by mutect2, pindel
- COL9A1 | c.1101del p.T368Qfs*11 | Frame Shift Del (DEL) | VAF 14/63 reads (22%) | called by mutect2, pindel, varscan2
- COL9A3 | c.607dup p.E203Gfs*10 | Frame Shift Ins (INS) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- DMRTB1 | c.697del p.L233Cfs*77 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | called by mutect2, pindel, varscan2
- GCLC | c.1914_*19del | Nonstop Mutation (DEL) | VAF 17/80 reads (21%) | called by mutect2, pindel*
- LILRA6 | c.956-2A>T p.X319_splice | Splice Site (SNP) | VAF 10/79 reads (13%) | called by muse, mutect2, varscan2
- LIMD1 | c.1957_1967del p.F653Lfs*33 | Frame Shift Del (DEL) | VAF 45/154 reads (29%) | called by mutect2, pindel, varscan2
- LTA4H | c.1160del p.G387Afs*19 | Frame Shift Del (DEL) | VAF 27/154 reads (18%) | called by mutect2, pindel, varscan2
- NYAP1 | c.1714del p.V572Cfs*2 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- OR8G2P | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- PAPPA2 | c.4171G>T p.G1391W | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- RIMBP3 | c.4160G>C p.C1387S | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SYT4 | c.1050del p.N351Mfs*20 | Frame Shift Del (DEL) | VAF 22/122 reads (18%) | called by mutect2, pindel, varscan2
- TRPC5 | c.7del p.Q3Nfs*21 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, pindel*, varscan2
- VN1R5 | c.857C>A p.T286K | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- WDFY3 | c.493dup p.H165Pfs*4 | Frame Shift Ins (INS) | VAF 5/35 reads (14%) | called by mutect2, pindel, varscan2
- ZFP2 | c.92A>C p.Q31P | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.55); called by muse, mutect2
- ALG14 | c.348C>T p.P116= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV100930827; called by muse, mutect2, varscan2
- ALPK2 | c.1320G>A p.T440= | Silent (SNP) | VAF 20/146 reads (14%) | catalogued as rs749447061, COSV100864170; called by muse, mutect2, varscan2
- ANGPT4 | c.1179G>A p.Q393= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV67922851; called by muse, mutect2, varscan2
- ANKRD30A | c.1353A>T p.A451= (on ENST00000611781; = p.A395= on NM_052997.2) | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100653041; called by muse, mutect2, varscan2
- ANKRD34A | c.276G>T p.A92= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100041156; called by muse, mutect2, varscan2
- ATRX | c.1062G>A p.K354= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV100970186; called by muse, mutect2
- BEST2 | c.1467C>T p.P489= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV99244266; called by muse, mutect2, varscan2
- BMPER | c.1479C>T p.L493= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99779026; called by mutect2, varscan2
- BTG1 | c.348A>G p.G116= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV99755336; called by muse, mutect2
- CCDC141 | c.3192G>C p.P1064= | Silent (SNP) | VAF 41/130 reads (32%) | catalogued as COSV99836281; called by muse, mutect2, varscan2
- CLCNKA | c.1011C>T p.S337= | Silent (SNP) | VAF 39/187 reads (21%) | catalogued as COSV100509909; called by muse, mutect2, varscan2
- CNNM4 | c.792C>T p.L264= | Silent (SNP) | VAF 58/187 reads (31%) | catalogued as COSV100998610; called by muse, mutect2, varscan2
- COL22A1 | c.1017T>A p.A339= | Silent (SNP) | VAF 31/134 reads (23%) | catalogued as COSV100276724; called by muse, mutect2, varscan2
- COMMD4 | c.450G>T p.V150= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV99143110; called by muse, mutect2, varscan2
- CPS1 | c.4308T>C p.I1436= | Silent (SNP) | VAF 31/153 reads (20%) | catalogued as COSV99242347; called by muse, mutect2, varscan2
- CSMD3 | c.3090T>C p.S1030= (on ENST00000297405 / NM_001363185.1; = p.S926= on NM_052900.3) | Silent (SNP) | VAF 51/148 reads (34%) | catalogued as COSV99826969; called by muse, mutect2, varscan2
- CTBP1 | c.315C>T p.I105= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs1388189912, COSV99337531; called by muse, mutect2, varscan2
- DNA2 | c.1908G>A p.K636= | Silent (SNP) | VAF 42/141 reads (30%) | catalogued as rs767980817, COSV100622412; called by muse, mutect2, varscan2
- EPHB1 | c.21A>G p.L7= | Silent (SNP) | VAF 121/267 reads (45%) | catalogued as rs1310826251, COSV101212763; called by muse, mutect2, varscan2
- ERN1 | c.2787C>T p.F929= | Silent (SNP) | VAF 5/113 reads (4%) | catalogued as COSV101458389, COSV101458396; called by muse, mutect2
- FAM47A | c.711G>T p.P237= | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as COSV100649762; called by muse, mutect2, varscan2
- FAM71B | c.1371G>C p.A457= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as rs369862230, COSV100261902, COSV57231747; called by muse, mutect2, varscan2
- FBN3 | c.1134G>A p.A378= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs779121529, COSV99560088, COSV99561751; called by muse, mutect2, varscan2
- FGF13 | c.663G>T p.G221= | Silent (SNP) | VAF 44/81 reads (54%) | catalogued as COSV100263738; called by muse, mutect2, varscan2
- FUT6 | c.480C>T p.S160= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs756621029, COSV54606710, COSV99744308; called by muse, mutect2, varscan2
- GLP1R | c.1317C>A p.P439= | Silent (SNP) | VAF 25/156 reads (16%) | catalogued as COSV100952476; called by muse, mutect2, varscan2
- HEATR6 | c.3258G>A p.S1086= | Silent (SNP) | VAF 42/140 reads (30%) | catalogued as rs770171377, COSV99482146; called by muse, mutect2, varscan2
- IFNA4 | c.429G>A p.V143= | Silent (SNP) | VAF 12/358 reads (3%) | called by muse, mutect2
- IHH | c.246C>A p.T82= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV99838608; called by muse, mutect2, varscan2
- IKBKE | c.1344G>A p.E448= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV100898105; called by muse, mutect2, varscan2
- ING1 | c.558G>T p.P186= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100311883, COSV100311964; called by muse, mutect2, varscan2
- INSR | c.1521A>T p.T507= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100251633; called by muse, mutect2, varscan2
- IRX1 | c.207G>T p.P69= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100116281; called by muse, mutect2
- KIAA1522 | c.342C>G p.S114= (on ENST00000373480 / NM_001198972.2; = p.S173= on NM_020888.3) | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99614215, COSV99614229; called by muse, mutect2, varscan2
- KIR3DL2 | c.528C>A p.S176= | Silent (SNP) | VAF 90/271 reads (33%) | called by muse, mutect2, varscan2
- LAMA4 | c.5035A>C p.R1679= (on ENST00000230538 / NM_001105206.3; = p.R1672= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/166 reads (31%) | catalogued as COSV100037724; called by muse, mutect2, varscan2
- LGR6 | c.2697G>A p.V899= (on ENST00000367278 / NM_001017403.1; = p.V847= on NM_021636.3) | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV55167827; called by muse, mutect2, varscan2
- LILRB2 | c.174C>T p.Y58= | Silent (SNP) | VAF 47/133 reads (35%) | catalogued as COSV100079069; called by muse, mutect2, varscan2
- LILRB3 | c.327C>A p.P109= | Silent (SNP) | VAF 15/183 reads (8%) | called by muse, mutect2
- MAGEB6 | c.862C>T p.L288= | Silent (SNP) | VAF 52/95 reads (55%) | catalogued as COSV100983674; called by muse, mutect2, varscan2
- MET | c.1233G>A p.A411= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as rs374081963; ClinVar: likely benign; called by muse, mutect2, varscan2
- MKRN3 | c.1008C>T p.N336= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as rs1424125161, COSV100090840; called by muse, mutect2, varscan2
- MROH2B | c.4135C>A p.R1379= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV101270554; called by muse, mutect2, varscan2
- MUC16 | c.39465C>G p.P13155= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV101109665, COSV101109988; called by muse, mutect2, varscan2
- MUC16 | c.8229G>T p.S2743= | Silent (SNP) | VAF 22/169 reads (13%) | catalogued as COSV101198441, COSV67443037; called by muse, mutect2, varscan2
- MUC5AC | c.13890G>C p.L4630= | Silent (SNP) | VAF 95/225 reads (42%) | catalogued as rs749628617, COSV100611334; called by muse, mutect2, varscan2
- MUTYH | c.468G>T p.L156= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100587946; called by muse, mutect2, varscan2
- MYBPC2 | c.633C>T p.P211= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs920066874, COSV100731640; called by muse, mutect2
- MYH14 | c.4719A>T p.T1573= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV51832856; called by muse, mutect2
- N6AMT1 | c.429T>A p.A143= | Silent (SNP) | VAF 60/152 reads (39%) | catalogued as COSV100374885; called by muse, mutect2, varscan2
- NRAP | c.3966C>T p.P1322= (on ENST00000359988 / NM_001322945.2; = p.P1287= on NM_006175.4) | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as rs781085088, COSV100748307, COSV63494679; called by muse, mutect2, varscan2
- NTM | c.624C>A p.A208= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100867239, COSV100867633; called by muse, mutect2, varscan2
- OR10X1 | c.798C>A p.I266= | Silent (SNP) | VAF 21/231 reads (9%) | catalogued as COSV100936600, COSV63767338; called by muse, mutect2, varscan2
- OR6F1 | c.700C>A p.R234= | Silent (SNP) | VAF 17/242 reads (7%) | catalogued as rs200002263, COSV57468109, COSV57468895; called by muse, mutect2
- OR8D2 | c.132C>T p.G44= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV100658913; called by muse, mutect2, varscan2
- OSBPL6 | c.2343G>T p.V781= | Silent (SNP) | VAF 23/144 reads (16%) | catalogued as COSV99506804; called by muse, mutect2, varscan2
- PDE10A | c.1668G>T p.L556= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as COSV100604600; called by muse, mutect2, varscan2
- PKN1 | c.1293G>A p.L431= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV99660960; called by muse, mutect2, varscan2
- PPP1R1B | c.600T>A p.S200= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99566114; called by muse, mutect2, varscan2
- PTGDR | c.204G>T p.L68= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100035479; called by muse, mutect2, varscan2
- RBFOX1 | c.351G>A p.K117= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV100299992; called by muse, mutect2, varscan2
- RDH13 | c.375G>T p.A125= (on ENST00000415061 / NM_001145971.2; = p.A54= on NM_138412.4) | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV99401400; called by muse, mutect2, varscan2
- RPRD1B | c.576A>G p.S192= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as rs1456041368, COSV100987183; called by muse, mutect2, varscan2
- SHOX2 | c.594A>G p.Q198= (on ENST00000441443 / NM_006884.3; = p.Q222= on NM_003030.4) | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV101273749, COSV67463767; called by muse, mutect2, varscan2
- SLC12A5 | c.2211C>A p.T737= (on ENST00000454036 / NM_001134771.2; = p.T714= on NM_020708.5) | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1026017018, COSV99715485; called by muse, mutect2
- SLC28A2 | c.1272A>T p.A424= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV100754636; called by muse, mutect2
- SLC35C1 | c.273C>T p.L91= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs886279110, COSV100029341; called by muse, mutect2, varscan2
- SLC39A8 | c.459A>T p.I153= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as COSV100765658; called by muse, mutect2, varscan2
- SLITRK1 | c.1917C>A p.L639= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV65678101; called by muse, mutect2, varscan2
- SNX20 | c.333C>A p.A111= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs749271055, COSV100319128, COSV56056795; called by muse, mutect2, varscan2
- STK24 | c.630G>T p.S210= | Silent (SNP) | VAF 49/177 reads (28%) | catalogued as COSV100924934, COSV100925012, COSV100925013; called by muse, mutect2, varscan2
- SYNPO2L | c.1086C>T p.A362= (on ENST00000394810 / NM_001114133.3; = p.A138= on NM_024875.5) | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as COSV100866327; called by muse, mutect2
- TDP1 | c.1809C>T p.N603= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV100187617; called by muse, mutect2
- THSD7B | c.759G>A p.L253= | Silent (SNP) | VAF 23/143 reads (16%) | catalogued as COSV55745624, COSV99745779; called by muse, mutect2, varscan2
- TIMELESS | c.1671G>A p.E557= | Silent (SNP) | VAF 84/212 reads (40%) | catalogued as rs371945970; called by muse, mutect2, varscan2
- TMEM39A | c.1398C>T p.L466= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as COSV100052295; called by muse, mutect2, varscan2
- TMEM82 | c.828C>T p.F276= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs144951649, COSV65387181; called by muse, mutect2
- TRPM3 | c.3849C>T p.N1283= (on ENST00000357533 / NM_001366142.2; = p.N1138= on NM_020952.6) | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as rs781445129, COSV100676780, COSV62588478; called by muse, mutect2, varscan2
- TSR1 | c.87G>A p.R29= | Silent (SNP) | VAF 74/368 reads (20%) | catalogued as COSV99279815; called by muse, varscan2
- TTN | c.13842G>A p.G4614= (on ENST00000591111; = p.G3687= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100598044; called by muse, mutect2, varscan2
- TUBB1 | c.954G>A p.R318= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV99413931; called by muse, mutect2, varscan2
- TUBB2B | c.177T>C p.Y59= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV99455311; called by muse, mutect2, varscan2
- UBR4 | c.13863G>T p.P4621= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs540655585, COSV100920401, COSV64391014; called by muse, mutect2, varscan2
- VAX1 | c.171T>A p.A57= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV99523981; called by muse, mutect2, varscan2
- VPS13A | c.7278A>G p.Q2426= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs554457655, COSV100652286; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZBED9 | c.645A>T p.A215= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV101509140; called by muse, mutect2, varscan2
- ZNF208 | c.672T>A p.T224= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV101236877; called by muse, mutect2, varscan2
- ZNF462 | c.1011G>A p.K337= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99470968; called by muse, mutect2, varscan2
- ZNF80 | c.363G>T p.L121= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV100351940; called by muse, mutect2, varscan2
- ZRANB3 | c.807C>A p.V269= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99922779; called by muse, mutect2, varscan2
- ZSCAN4 | c.681T>A p.G227= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV99989794; called by muse, mutect2, varscan2
- ADGRE4P | n.316C>A | RNA (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- CXCL12 | c.267-2613C>A | Intron (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100638879; called by muse, mutect2, varscan2
- HERC2P3 | n.901A>G | RNA (SNP) | VAF 19/181 reads (10%) | called by muse, mutect2, varscan2
- SSPOP | n.4408C>A | RNA (SNP) | VAF 13/57 reads (23%) | catalogued as COSV100022210, COSV100022541; called by muse, mutect2, varscan2
